Somatic mutation profile of tumor specimen TCGA-WC-A883-01A (aliquot TCGA-WC-A883-01A-12D-A39W-08) from TCGA case TCGA-WC-A883, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 76.5 years (27,953 days).
Specimen TCGA-WC-A883-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b35e4b9-63b4-4f05-8c3d-67d528a5a54c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WC-A883-10A (Blood Derived Normal), aliquot TCGA-WC-A883-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c623c1e9-f5d7-4b9d-a38f-d2f0f00c00f3

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 27/69 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MATN4 | c.1457G>A p.R486H (on ENST00000372754; = p.R445H on NM_003833.4) | Missense Mutation (SNP) | VAF 38/55 reads (69%) | PolyPhen probably damaging (0.909); catalogued as rs150948243; called by muse, mutect2, varscan2
- NOP14 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs145122268; called by muse, mutect2, varscan2
- USP15 | c.1256C>T p.A419V (on ENST00000280377 / NM_001351159.2; = p.A390V on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1483593421; called by muse, mutect2, varscan2
- DGKK | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 94/204 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- JAK1 | c.483+1G>A p.X161_splice | Splice Site (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- PSG4 | c.377A>T p.K126M | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ZNF462 | c.5105G>A p.C1702Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EMID1 | c.387G>T p.R129= | Silent (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- UBA6 | c.822T>C p.G274= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as rs1414055928; called by muse, mutect2, varscan2
